Somatic mutation profile of tumor specimen C3N-02145-03 (aliquot CPT0118570006) from CPTAC case C3N-02145, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.4 years (24,986 days).
Specimen C3N-02145-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39ba194d-43ac-4e96-8419-17d1f35c0b02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02145-31 (Blood Derived Normal), aliquot CPT0119810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69465385-b576-43d1-8f32-899bc75f7706

The open-access MAF lists 48 somatic variants for this specimen: 24 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 14, 5'UTR 3, Intron 3, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, RNA 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 111/535 reads (21%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- LAMA2 | c.5259del p.V1754* | Frame Shift Del (DEL) | VAF 50/197 reads (25%) | catalogued as rs1211739649; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CDCA7 | c.355G>A p.A119T (on ENST00000347703 / NM_145810.3; = p.A198T on NM_031942.5) | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); catalogued as rs1200231071; called by muse, mutect2, varscan2
- CSF2RB | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs146859739; called by muse, mutect2, varscan2
- CYP11A1 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 54/305 reads (18%) | catalogued as rs755186597, CM1210478, COSV99165954; called by muse, mutect2, varscan2
- GPAT2 | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as rs547386788; called by muse, mutect2, varscan2
- NLRP2 | c.2836T>C p.C946R | Missense Mutation (SNP) | VAF 169/526 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1453006401, COSV99672139; called by muse, mutect2, varscan2
- PACS2 | c.287_289del p.F96del | In Frame Del (DEL) | VAF 28/228 reads (12%) | catalogued as rs1425778118; called by mutect2, pindel, varscan2
- PORCN | c.1133C>A p.S378* (on ENST00000326194 / NM_203475.3; = p.S367* on NM_022825.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 81/707 reads (11%) | catalogued as COSV100400607; called by muse, mutect2, varscan2
- SMAD4 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 13/409 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV61688931; called by muse, mutect2
- WSB1 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 29/318 reads (9%) | catalogued as rs1243405786, COSV52214529; called by muse, mutect2
- APC | c.8155_8164del p.E2719* | Frame Shift Del (DEL) | VAF 62/188 reads (33%) | called by mutect2, pindel, varscan2
- CLSTN1 | c.2628C>G p.I876M (on ENST00000377298 / NM_001009566.3; = p.I866M on NM_014944.4) | Missense Mutation (SNP) | VAF 96/327 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DEFB133 | c.166A>C p.N56H | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ERRFI1 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 120/354 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC1 | c.605A>C p.Q202P | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LEPR | c.2230C>A p.L744I | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PTBP2 | c.718C>G p.Q240E (on ENST00000426398 / NM_001300986.2; = p.Q232E on NM_021190.4) | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); called by muse, varscan2
- RYR2 | c.2492A>G p.K831R | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0.014); called by muse, mutect2
- STAU2 | c.1010G>T p.R337L (on ENST00000524300 / NM_001164380.2; = p.R305L on NM_014393.2) | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC6 | c.1716G>A p.M572I | Missense Mutation (SNP) | VAF 192/1267 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, varscan2
- VWCE | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- WEE2 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANKRD30B | c.2013A>G p.R671= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- APBB1IP | c.1848C>T p.S616= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1447144865; called by muse, mutect2
- BAP1 | c.153A>G p.K51= | Silent (SNP) | VAF 60/186 reads (32%) | called by muse, mutect2
- DRD2 | c.337C>T p.L113= | Silent (SNP) | VAF 60/428 reads (14%) | called by muse, mutect2, varscan2
- FAM71B | c.1077G>A p.S359= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs369213663, COSV57228490; called by muse, mutect2, varscan2
- FFAR2 | c.441T>C p.V147= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- GLG1 | c.2365C>T p.L789= | Silent (SNP) | VAF 56/180 reads (31%) | called by muse, mutect2, varscan2
- MASP1 | c.1923C>T p.A641= | Silent (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- OR2T11 | c.177G>T p.L59= | Silent (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- PRDM1 | c.327G>A p.K109= | Silent (SNP) | VAF 24/198 reads (12%) | called by muse, varscan2
- PTBP2 | c.657C>T p.I219= (on ENST00000426398 / NM_001300986.2; = p.I211= on NM_021190.4) | Silent (SNP) | VAF 22/135 reads (16%) | called by muse, varscan2
- SLC7A2 | c.1695A>T p.P565= (on ENST00000494857 / NM_001370338.1; = p.P604= on NM_003046.6) | Silent (SNP) | VAF 16/94 reads (17%) | called by mutect2, varscan2
- TDRD7 | c.1092A>C p.A364= | Silent (SNP) | VAF 131/436 reads (30%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.1533C>T p.S511= | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as rs771385745, COSV100695210; called by muse, mutect2, varscan2
- CPLANE1 | c.*3209C>T | 3'UTR (SNP) | VAF 37/166 reads (22%) | catalogued as COSV57076940; called by muse, mutect2, varscan2
- EP400P1 | n.1542C>G | RNA (SNP) | VAF 22/75 reads (29%) | catalogued as rs1298590938; called by muse, mutect2, varscan2
- ERGIC3 | c.685+305G>T | Intron (SNP) | VAF 36/357 reads (10%) | called by muse, mutect2
- FAAP20 | chr1:2198080 T>C | 5'Flank (SNP) | VAF 32/201 reads (16%) | called by muse, mutect2, varscan2
- HSPE1 | c.259-15T>G | Intron (SNP) | VAF 53/215 reads (25%) | called by muse, mutect2, varscan2
- PA2G4 | c.-157C>T | 5'UTR (SNP) | VAF 55/350 reads (16%) | catalogued as rs746344277, COSV99915827; called by muse, mutect2, varscan2
- PEX19 | c.-9G>T | 5'UTR (SNP) | VAF 40/361 reads (11%) | catalogued as COSV99616361; called by muse, mutect2, varscan2
- POLR2D | c.-6G>A | 5'UTR (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- TCOF1 | c.1893+16G>A | Intron (SNP) | VAF 102/299 reads (34%) | called by muse, mutect2, varscan2
- WASF4P | n.1193C>A | RNA (SNP) | VAF 20/123 reads (16%) | called by muse, varscan2
